Somatic mutation profile of tumor specimen 0DJ6KP from CCDI case PBBWLX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (1,996 days).
Specimen 0DJ6KP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3092365-2777-4e93-9584-1c5d3ef7424c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9370b021-1c76-4180-a1c1-7356aa8019c4

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Silent 3, Frame Shift Ins 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MIB1 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 335/779 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs775799378; called by muse, mutect2, varscan2
- MLYCD | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 50/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371429195; called by muse, mutect2, varscan2
- RUNDC1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 150/1615 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs149556177; called by muse, mutect2
- RUVBL1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 283/702 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780977111; called by muse, mutect2, varscan2
- ANK1 | c.2608G>A p.V870M | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CHD5 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 487/855 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CXXC5 | c.182_186dup p.G63Rfs*36 | Frame Shift Ins (INS) | VAF 162/403 reads (40%) | called by mutect2, pindel, varscan2
- NFIX | c.1423T>G p.S475A (on ENST00000592199 / NM_001365902.3; = p.P425= on NM_002501.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/608 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- SIDT2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 118/436 reads (27%) | called by muse, mutect2, varscan2
- PKHD1 | c.210C>T p.P70= | Silent (SNP) | VAF 149/751 reads (20%) | catalogued as rs372103359, COSV100580947; called by muse, mutect2, varscan2
- RANBP2 | c.2172C>T p.D724= | Silent (SNP) | VAF 153/885 reads (17%) | called by muse, mutect2, varscan2
- TRPC6 | c.2466A>G p.L822= | Silent (SNP) | VAF 15/449 reads (3%) | called by muse, mutect2
- ABHD18 | c.699+973G>A | Intron (SNP) | VAF 115/865 reads (13%) | called by muse, mutect2, varscan2
- DYSF | c.458-457C>T | Intron (SNP) | VAF 174/414 reads (42%) | catalogued as rs528489776; called by muse, mutect2, varscan2
- IQSEC3 | c.2710-72C>T | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as rs1011794258; called by muse, mutect2
- LINC02688 | chr11:1051769 C>T | 5'Flank (SNP) | VAF 25/315 reads (8%) | catalogued as rs888426946; called by muse, mutect2
- ZNF653 | c.1171+53G>A | Intron (SNP) | VAF 93/266 reads (35%) | catalogued as rs893284453; called by muse, mutect2, varscan2
